MMRF case MMRF_2215 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/1e298f2a-6617-4525-abde-08211e47dbe7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.9 years (26,246 days); ISS stage: I; Days to last known disease status: 893 days (2.4 years); Days to last follow up: 893 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 93 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 128 days; Days to treatment end: 128 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 129 days; Days to treatment end: 129 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 242 days; Days to treatment end: 423 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 428 days (1.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -20 (ECOG 0): M Protein 1.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.771 mg/dL; Immunoglobulin G 5.43 g/L; Immunoglobulin A 277 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 1.83 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 206 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 8.3 g/dL; Glucose 5.01 mmol/L.
- Day 72 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 4.35 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 4.24 mmol/L.
- Day 151 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.906 mg/dL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 6.05 mmol/L.
- Day 242 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.33 mmol/L; Albumin 37 g/L; Total Protein 6.6 g/dL; Glucose 4.51 mmol/L.
- Day 330 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.33 mg/dL; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 6.6 mmol/L.
- Day 414 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.73 mg/dL; Hemoglobin 6.76 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 7.32 mmol/L.
- Day 500 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.36 mg/dL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 1.98 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 4.57 mmol/L.
- Day 613 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.43 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Hemoglobin 7.44 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 5.17 mmol/L.
- Day 697 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.4 g/dL; Glucose 4.79 mmol/L.
- Day 781 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.8 mg/dL; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 893 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.56 mg/dL; Lactate Dehydrogenase 2.05 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.56 mmol/L.

Other clinical attributes
- Day -20: Weight: 80 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship primary diagnosis: Kidney Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2215_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -20 days.
- Sample MMRF_2215_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -20 days.
